FM case AD1676 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Esophagus.
https://portal.gdc.cancer.gov/cases/3a41da12-8a04-44a9-b10a-dbb1bc25fda7

Female, 68.1 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the esophagus; primary biopsied or resected from the esophagus. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
